Somatic mutation profile of tumor specimen fe591474-99d7-44d3-be73-c3b8ed (aliquot fe591474-99d7-44d3-be73-c3b8ed_D6_1) from CPTAC case 18BR002, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 64.0 years (23,390 days).
Specimen fe591474-99d7-44d3-be73-c3b8ed: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bf0f16b-aeb9-4e44-b8f3-2027f7a46c33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen bfcfa737-bf42-4249-b016-7d5ce1 (Blood Derived Normal), aliquot bfcfa737-bf42-4249-b016-7d5ce1_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67dafc9f-9eb2-44e9-95c3-dfa8957ea316

The open-access MAF lists 171 somatic variants for this specimen: 127 protein-altering or splice-affecting, 28 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 28, Nonsense Mutation 14, Intron 9, Frame Shift Del 3, 5'UTR 2, In Frame Del 2, RNA 2, Splice Site 2, Frame Shift Ins 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 43/136 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 82/517 reads (16%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD3 | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV59867404; called by muse, mutect2
- ANO8 | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs1477419730; called by muse, mutect2
- AP1B1 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773941143, COSV100434666, COSV58016003; called by muse, mutect2
- CDX2 | c.650C>G p.A217G | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs930415507; called by muse, mutect2
- CEBPA | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.315); catalogued as rs1162467731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPA | c.3149C>T p.A1050V | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs776431514; called by muse, mutect2, varscan2
- DCX | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as COSV57575745; called by muse, mutect2, varscan2
- DNAH17 | c.2071C>A p.Q691K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.621); catalogued as COSV101101194; called by muse, mutect2, varscan2
- DOCK6 | c.2431G>A p.V811I | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs771097164; called by muse, mutect2, varscan2
- FAT2 | c.3472C>T p.Q1158* | Nonsense Mutation (SNP) | VAF 29/214 reads (14%) | catalogued as COSV55812785; called by muse, mutect2, varscan2
- GPRASP2 | c.1869G>C p.M623I | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV100176473; called by muse, mutect2
- HMCN1 | c.12149G>C p.R4050P | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.69); catalogued as COSV54909944; called by muse, mutect2
- ITGA3 | c.2817C>G p.I939M | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.623); catalogued as COSV50306113; called by muse, mutect2, varscan2
- KNL1 | c.921G>A p.M307I (on ENST00000346991 / NM_170589.5; = p.M281I on NM_144508.5) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs759513987; called by mutect2, varscan2
- LIMK1 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs781884611, COSV60282865, COSV60283141; called by muse, mutect2, varscan2
- MYRFL | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs996558141, COSV101612433; called by muse, mutect2
- NSRP1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs761196282; called by muse, mutect2, varscan2
- NSRP1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs868110800; called by muse, mutect2, varscan2
- NUBP1 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as rs765995526; called by muse, mutect2, varscan2
- OR51A2 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as rs1194109989; called by muse, mutect2, varscan2
- RYR3 | c.11611C>T p.Q3871* (on ENST00000389232; = p.Q3872* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 8/173 reads (5%) | catalogued as rs1005595870; called by muse, mutect2
- SHISAL1 | c.330G>C p.L110F | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1275189655; called by muse, mutect2, varscan2
- STAB1 | c.2204G>A p.G735D | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217431452, COSV100401222; called by muse, mutect2, varscan2
- TCHHL1 | c.1549A>G p.T517A | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as rs761825623; called by muse, mutect2, varscan2
- TG | c.8071C>T p.R2691C | Missense Mutation (SNP) | VAF 18/265 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.564); catalogued as rs764239765; called by muse, mutect2
- TLK2 | c.691_693del p.K231del | In Frame Del (DEL) | VAF 30/126 reads (24%) | catalogued as rs779826427; called by pindel, varscan2
- TUT4 | c.2771C>G p.S924* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV57115142; called by muse, mutect2, varscan2
- UBN1 | c.3310C>G p.L1104V | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs1395561100; called by muse, mutect2, varscan2
- UGT1A7 | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1559339881; called by muse, mutect2
- USP8 | c.2648A>G p.D883G | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV56166959; called by muse, mutect2
- VCAN | c.2912A>G p.H971R | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.216); catalogued as rs767117438; called by muse, mutect2
- AOX1 | c.2580G>A p.M860I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ARHGAP23 | c.1630G>C p.A544P | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- ARHGEF38 | c.1033_1034del p.E345Rfs*5 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by pindel, varscan2
- ATXN1L | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- BNIP5 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C3orf52 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2
- C8orf82 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CASD1 | c.28A>C p.K10Q | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CD300A | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 42/380 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CENPF | c.4837C>G p.L1613V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- CHAT | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2
- CHRNA3 | c.82+1G>C p.X28_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- CNR2 | c.847T>G p.F283V | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A6 | c.4664G>T p.G1555V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CROCC | c.1160A>G p.Q387R | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0.01); called by muse, mutect2
- CTF1 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, varscan2
- DCHS1 | c.6981T>A p.Y2327* | Nonsense Mutation (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- DCST1 | c.1106G>C p.R369P | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DDB1 | c.621G>A p.W207* | Nonsense Mutation (SNP) | VAF 27/204 reads (13%) | called by muse, mutect2, varscan2
- DEDD2 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2
- DLK2 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- EIF2A | c.1410G>A p.M470I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ESCO2 | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM120C | c.2588T>C p.I863T | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); called by muse, mutect2
- FAM178B | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- FAT2 | c.2125C>T p.H709Y | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FRG2 | c.587A>G p.Q196R | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); called by muse, mutect2
- GCDH | c.449A>T p.H150L | Missense Mutation (SNP) | VAF 30/510 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); called by muse, mutect2
- H1-3 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- HERC2 | c.7269C>A p.S2423R | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, varscan2
- IGKV1-17 | c.13G>T p.V5F | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2
- KCNB2 | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDR | c.2980G>A p.D994N | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.409); called by muse, mutect2
- KLHDC2 | c.773+6T>A | Splice Region (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- KMT2D | c.8501C>T p.S2834L | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- KRT4 | c.1085T>G p.I362S | Missense Mutation (SNP) | VAF 90/403 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- L3HYPDH | c.377C>A p.A126E | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LMF1 | c.1504C>G p.P502A | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC37B | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 27/331 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.04); called by muse, mutect2
- LRRC8D | c.678G>C p.Q226H | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LTB4R2 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP4K5 | c.1017T>A p.F339L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- METTL21C | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MLLT10 | c.1859C>A p.P620H (on ENST00000307729 / NM_001195626.3; = p.P636H on NM_004641.3) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- MMP3 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.057); called by muse, mutect2
- MOBP | c.467C>T p.S156F (on ENST00000420739; = p.S180F on NM_001278322.2) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | PolyPhen benign (0.138); called by muse, mutect2, varscan2
- NBPF6 | c.1953G>C p.E651D | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2
- NCKIPSD | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- NCOA6 | c.3497C>G p.P1166R | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2
- NLRP12 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- NR2C1 | c.1440C>A p.F480L | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NR2C1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); called by muse, mutect2
- NUMA1 | c.3430G>A p.D1144N | Missense Mutation (SNP) | VAF 27/318 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.079); called by muse, mutect2
- NWD1 | c.2099C>G p.P700R | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.243); called by muse, mutect2
- OGA | c.1300C>G p.Q434E | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.12); called by muse, mutect2
- PCDHB1 | c.1755C>A p.Y585* | Nonsense Mutation (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- PIK3CA | c.29_53delinsA p.L10_P18delinsQ | In Frame Del (DEL) | VAF 18/44 reads (41%) | called by pindel, varscan2*
- PITPNM3 | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2
- PKD1L3 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- PLA2G2F | c.342C>A p.Y114* | Nonsense Mutation (SNP) | VAF 25/201 reads (12%) | called by muse, mutect2, varscan2
- PLXNB2 | c.3422C>A p.T1141K | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- PPP1R3F | c.1458G>T p.Q486H | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2
- PRSS45P | c.128C>G p.S43* | Nonsense Mutation (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2, varscan2
- PSD4 | c.2251G>T p.E751* | Nonsense Mutation (SNP) | VAF 17/142 reads (12%) | called by muse, mutect2, varscan2
- PTRH2 | c.257G>A p.C86Y | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- PYDC2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RAD9A | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); called by muse, mutect2
- RAG1 | c.2969T>G p.V990G | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- RYR2 | c.6373C>T p.Q2125* | Nonsense Mutation (SNP) | VAF 37/250 reads (15%) | called by muse, mutect2, varscan2
- SAP130 | c.1709G>A p.G570D | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SFMBT2 | c.1488-2A>C p.X496_splice | Splice Site (SNP) | VAF 19/80 reads (24%) | called by mutect2, varscan2
- SH3BP5L | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- SHROOM4 | c.4429G>C p.E1477Q | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMG1 | c.10459G>C p.E3487Q | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); called by muse, mutect2
- SNX14 | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2
- SOSTDC1 | c.393G>C p.W131C | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOSTDC1 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SYT15 | c.778del p.C260Afs*33 | Frame Shift Del (DEL) | VAF 15/136 reads (11%) | called by mutect2, varscan2
- TMEM67 | c.1882C>T p.L628F | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.144); called by muse, mutect2
- TNFRSF6B | c.125_141del p.E42Gfs*52 | Frame Shift Del (DEL) | VAF 27/298 reads (9%) | called by mutect2, pindel
- TNNI2 | c.291C>A p.N97K | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.006); called by muse, mutect2
- TRAV10 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- UBR5 | c.7495G>A p.D2499N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- UCKL1 | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 26/347 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- USP17L7 | c.1160G>C p.R387T | Missense Mutation (SNP) | VAF 102/430 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDFY4 | c.3626C>G p.S1209C | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- WDR87 | c.3974G>C p.R1325T | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.413); called by muse, mutect2
- WRNIP1 | c.1987A>T p.R663W | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZBTB20 | c.1234G>C p.A412P (on ENST00000474710 / NM_001164342.2; = p.A339P on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/467 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- ZBTB8B | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZFHX4 | c.8190dup p.D2731* | Frame Shift Ins (INS) | VAF 12/98 reads (12%) | called by mutect2, pindel, varscan2
- ZNF106 | c.4315G>A p.D1439N | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.136); called by muse, mutect2
- ZNF300 | c.948G>C p.Q316H | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.3); called by muse, mutect2
- ZNF875 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARL14EP | c.249G>A p.K83= | Silent (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2, varscan2
- CASS4 | c.699A>C p.T233= | Silent (SNP) | VAF 94/205 reads (46%) | called by muse, mutect2, varscan2
- CSTB | c.60C>G p.A20= | Silent (SNP) | VAF 13/154 reads (8%) | called by muse, mutect2
- DSCAM | c.4005G>C p.R1335= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV68027685; called by muse, mutect2, varscan2
- DZIP1 | c.990G>A p.Q330= | Silent (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- EFNA4 | c.81C>A p.R27= | Silent (SNP) | VAF 22/99 reads (22%) | called by muse, varscan2
- FAT2 | c.2331C>G p.P777= | Silent (SNP) | VAF 22/172 reads (13%) | called by muse, mutect2, varscan2
- GGT1 | c.531C>A p.A177= | Silent (SNP) | VAF 42/239 reads (18%) | called by muse, mutect2, varscan2
- GYG2 | c.246C>T p.V82= | Silent (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- KIF13A | c.1866C>T p.L622= | Silent (SNP) | VAF 31/187 reads (17%) | called by muse, mutect2, varscan2
- KIF18B | c.1872C>G p.P624= (on ENST00000593135 / NM_001265577.2; = p.P636= on NM_001264573.2) | Silent (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- MYH4 | c.228A>G p.Q76= | Silent (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- NIBAN2 | c.63C>T p.T21= | Silent (SNP) | VAF 61/130 reads (47%) | catalogued as rs111851615; called by muse, mutect2, varscan2
- NPEPL1 | c.1107C>T p.A369= | Silent (SNP) | VAF 29/163 reads (18%) | called by muse, mutect2, varscan2
- NRAP | c.186C>T p.N62= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- NUP205 | c.1854C>G p.L618= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- OR10AD1 | c.591G>C p.L197= | Silent (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- PCDH18 | c.2406C>G p.L802= | Silent (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.1761G>A p.S587= | Silent (SNP) | VAF 19/307 reads (6%) | catalogued as rs782634339, COSV53838691; called by muse, mutect2
- POTED | c.285G>A p.R95= | Silent (SNP) | VAF 92/457 reads (20%) | catalogued as COSV100202972; called by muse, mutect2, varscan2
- PSD2 | c.2274T>G p.T758= | Silent (SNP) | VAF 18/176 reads (10%) | called by muse, mutect2
- RAPGEF3 | c.2133C>T p.F711= (on ENST00000389212; = p.F669= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/276 reads (4%) | catalogued as COSV99406719; called by muse, mutect2
- RFC4 | c.348A>T p.I116= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- RSPO2 | c.666G>A p.R222= | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- RUBCN | c.2835G>A p.Q945= | Silent (SNP) | VAF 16/258 reads (6%) | catalogued as rs1560394929; called by muse, mutect2
- SMS | c.90C>T p.F30= | Silent (SNP) | VAF 13/212 reads (6%) | called by muse, mutect2
- VILL | c.90G>T p.G30= | Silent (SNP) | VAF 23/184 reads (13%) | called by muse, mutect2, varscan2
- ZBP1 | c.247T>C p.L83= | Silent (SNP) | VAF 19/370 reads (5%) | called by muse, mutect2
- AGPAT4 | c.348+4996C>T | Intron (SNP) | VAF 20/302 reads (7%) | called by muse, mutect2
- AL353804.4 | chrX:73822374 G>A | 5'Flank (SNP) | VAF 29/309 reads (9%) | called by muse, mutect2
- ALDH3A1 | c.394+67G>T | Intron (SNP) | VAF 37/201 reads (18%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-382C>T | 5'UTR (SNP) | VAF 29/167 reads (17%) | catalogued as COSV58126604; called by muse, mutect2, varscan2
- CHCHD3 | c.525-19039G>C | Intron (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- GRSF1 | c.357+91C>G | Intron (SNP) | VAF 10/45 reads (22%) | catalogued as rs1468208995, COSV54656826; called by muse, mutect2, varscan2
- HLA-L | n.507C>G | RNA (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- HROB | c.-96C>T | 5'UTR (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- IRAK1 | c.*756C>G | 3'UTR (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- NTHL1 | c.709+27C>G | Intron (SNP) | VAF 45/258 reads (17%) | catalogued as rs112375837; called by muse, mutect2, varscan2
- PABPC4 | c.1405+16C>G | Intron (SNP) | VAF 10/153 reads (7%) | called by muse, mutect2
- RAB40C | chr16:629590 C>G | 3'Flank (SNP) | VAF 17/323 reads (5%) | called by muse, mutect2
- SCOC-AS1 | n.297T>A | RNA (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- TCP11 | c.124+188G>C | Intron (SNP) | VAF 14/98 reads (14%) | called by muse, varscan2
- TNFRSF10C | c.60+25C>T | Intron (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- UPK1A | c.85-107G>A | Intron (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
